Somatic mutation profile of tumor specimen C3L-04795-02 (aliquot CPT0257640006) from CPTAC case C3L-04795, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 37.0 years (13,503 days).
Specimen C3L-04795-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03fe4942-1616-476f-8493-00187efa6cd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04795-31 (Blood Derived Normal), aliquot CPT0257730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01bfe35e-69ac-446f-a708-0db048f58035

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 6, Intron 3, 3'Flank 3, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 73/189 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 248/509 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- TP53 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 511/566 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100400890; called by muse, mutect2, varscan2
- CARS2 | c.571+2T>C p.X191_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as rs749363417, COSV99959286; called by muse, mutect2
- CNGB1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 192/454 reads (42%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs200052038; called by muse, mutect2, varscan2
- EPG5 | c.6950C>T p.A2317V | Missense Mutation (SNP) | VAF 247/560 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56354653; called by muse, mutect2, varscan2
- GALNT9 | c.1310G>A p.R437H (on ENST00000328957 / NM_001122636.2; = p.R71H on NM_021808.3) | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767618128, COSV61101867; called by muse, mutect2, varscan2
- GIMAP6 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 149/341 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs752336307, COSV61032503; called by muse, mutect2, varscan2
- GLIS2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 197/417 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs759084039; called by muse, mutect2, varscan2
- LRRC73 | c.514A>G p.S172G | Missense Mutation (SNP) | VAF 85/174 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as rs1162709486; called by muse, mutect2, varscan2
- LRRK1 | c.2348G>A p.R783H | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs777040315; called by muse, mutect2, varscan2
- MUC16 | c.15791C>A p.S5264Y | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as rs1469551979, COSV67466282; called by muse, mutect2, varscan2
- MUC5B | c.10939C>T p.R3647C | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs779606866; called by mutect2, varscan2
- NLRP2 | c.1675G>A p.G559S | Missense Mutation (SNP) | VAF 177/430 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1166604729; called by muse, mutect2, varscan2
- PHF2 | c.3115C>T p.R1039C | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375390580; called by muse, mutect2, varscan2
- PPP1R9A | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56894690; called by muse, mutect2, varscan2
- SLITRK5 | c.2353A>G p.T785A | Missense Mutation (SNP) | VAF 94/106 reads (89%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs375873159; called by muse, mutect2, varscan2
- TMC4 | c.820G>C p.V274L (on ENST00000617472 / NM_001145303.3; = p.V268L on NM_144686.4) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs765150409; called by muse, mutect2, varscan2
- ADCY5 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); called by muse, varscan2
- ARID4B | c.1217T>C p.M406T | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ATRX | c.3689_3692del p.T1230Kfs*3 | Frame Shift Del (DEL) | VAF 46/54 reads (85%) | called by mutect2, pindel, varscan2
- ENAM | c.3325A>T p.N1109Y | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ESYT2 | c.1591G>T p.D531Y (on ENST00000613624; = p.D455Y on NM_020728.3) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KDM1B | c.2278A>C p.T760P (on ENST00000449850; = p.T527P on NM_153042.4) | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- KIF4B | c.851G>C p.S284T | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KLHL24 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NSD2 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 37/671 reads (6%) | called by muse, mutect2
- OR4A15 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SNRNP35 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TDRD10 | c.12C>G p.N4K | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, varscan2
- USP32 | c.4691A>G p.Y1564C | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VAV2 | c.1871C>T p.P624L (on ENST00000371850 / NM_001134398.2; = p.P614L on NM_003371.4) | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF697 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 146/320 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZNF875 | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- BNC2 | c.2925T>C p.H975= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs1490782071; called by muse, mutect2, varscan2
- CDHR2 | c.2886C>T p.G962= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as rs1024163051; called by muse, mutect2
- CTBP1 | c.513G>A p.R171= | Silent (SNP) | VAF 146/506 reads (29%) | catalogued as rs1330407170; called by muse, mutect2, varscan2
- LAMA3 | c.3288G>A p.S1096= | Silent (SNP) | VAF 300/728 reads (41%) | catalogued as rs368422951; called by muse, mutect2, varscan2
- PGAP4 | c.549G>A p.S183= | Silent (SNP) | VAF 259/604 reads (43%) | catalogued as rs535197432, COSV66388136; called by muse, mutect2, varscan2
- PITRM1 | c.1161C>T p.A387= | Silent (SNP) | VAF 83/220 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621297 C>G | 3'Flank (SNP) | VAF 128/1950 reads (7%) | called by muse, mutect2
- ARHGEF25 | chr12:57621424 C>G | 3'Flank (SNP) | VAF 120/2066 reads (6%) | called by muse, mutect2
- ARHGEF25 | chr12:57621768 C>G | 3'Flank (SNP) | VAF 232/4534 reads (5%) | called by muse, mutect2
- CCDC148 | c.26-7449G>A | Intron (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- EIF3H | c.290-30152A>G | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as rs983189100; called by muse, mutect2, varscan2
- IMPA2 | c.231-1373G>A | Intron (SNP) | VAF 82/226 reads (36%) | called by muse, mutect2, varscan2
